Somatic mutation profile of tumor specimen ALCH-AE09-TTP1-A (aliquot ALCH-AE09-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-AE09, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.5 years (23,198 days).
Specimen ALCH-AE09-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b98585de-c33d-4c06-8c71-d600d7847f3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE09-NB1-A (Blood Derived Normal), aliquot ALCH-AE09-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2333a910-d1c3-46bd-946e-9a36c760c6c6

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 4, Nonsense Mutation 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC2 | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213879384, COSV60572325; called by muse, mutect2, varscan2
- DHX34 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs149967464, COSV60898381; called by muse, mutect2, varscan2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 112/754 reads (15%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- ENDOV | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs762904750; called by muse, mutect2, varscan2
- HSD11B2 | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981001, CX952214; called by mutect2, varscan2
- KCNQ3 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs370369681; called by muse, mutect2, varscan2
- OXNAD1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 16/413 reads (4%) | catalogued as COSV53266592; called by muse, mutect2
- SPACA1 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as COSV52759597; called by muse, varscan2
- TRA2B | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as rs1303854859, COSV52026108; called by muse, mutect2, varscan2
- ZFR2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs751547243; called by mutect2, varscan2
- C2CD3 | c.2387G>A p.G796E | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- CCDC14 | c.1628A>G p.K543R (on ENST00000488653; = p.K495R on NM_022757.5) | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- DDX43 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- HEATR3 | c.1205G>C p.S402T | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL31 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2
- MUC12 | c.12761C>A p.P4254Q (on ENST00000379442; = p.P4111Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 66/1378 reads (5%) | SIFT deleterious (0); called by muse, mutect2
- PIK3R5 | c.20C>G p.T7R | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SETD2 | c.6853C>T p.Q2285* | Nonsense Mutation (SNP) | VAF 54/272 reads (20%) | called by muse, mutect2, varscan2
- TLR4 | c.1169G>A p.C390Y (on ENST00000355622 / NM_138554.5; = p.C350Y on NM_003266.4) | Missense Mutation (SNP) | VAF 169/691 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM229B | c.350C>A p.T117N | Missense Mutation (SNP) | VAF 24/604 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UNC13A | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- ANKH | c.351G>C p.L117= | Silent (SNP) | VAF 304/817 reads (37%) | called by muse, mutect2, varscan2
- BNC2 | c.513C>A p.I171= | Silent (SNP) | VAF 17/520 reads (3%) | called by muse, mutect2
- CRISP1 | c.711C>T p.F237= | Silent (SNP) | VAF 16/468 reads (3%) | called by muse, mutect2
- CSMD1 | c.5883T>A p.V1961= (on ENST00000520002; = p.V1960= on NM_033225.6) | Silent (SNP) | VAF 40/556 reads (7%) | called by muse, mutect2
- HCN1 | c.570G>T p.L190= | Silent (SNP) | VAF 75/480 reads (16%) | catalogued as COSV57513866; called by muse, mutect2, varscan2
- KIF13B | c.4935G>T p.P1645= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- PDIA5 | c.1014T>A p.T338= | Silent (SNP) | VAF 42/202 reads (21%) | called by muse, mutect2, varscan2
- ZNF235 | c.96G>C p.L32= | Silent (SNP) | VAF 14/438 reads (3%) | called by muse, mutect2
- C11orf52 | c.*2C>T | 3'UTR (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- CEP68 | c.2007+39G>C | Intron (SNP) | VAF 112/679 reads (16%) | catalogued as rs201954531; called by muse, mutect2, varscan2
- GASK1A | c.1413+166A>G | Intron (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2
- TOPBP1 | c.3592+44del | Intron (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- TSC1 | c.211-40C>T | Intron (SNP) | VAF 81/339 reads (24%) | called by muse, mutect2, varscan2
